Gene-level copy-number profile of tumor specimen TCGA-BG-A18C-01A from TCGA case TCGA-BG-A18C, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 72.8 years (26,602 days).
Specimen TCGA-BG-A18C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.4a197c6b-20f4-4b94-acd4-738da9837178.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BG-A18C-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4c02f809-6423-468d-9ecf-f01d07003ece

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 27,540; copy number 2: 30,131; copy number 3: 1,619; copy number 4: 499.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BG-A18C-01A-11D-A12G-01): tumor purity 0.86, ploidy 1.66, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–1): RB1.
- chr13:48,340,797–49,444,064, 21 genes (within-gene range 0–1): AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L.
- chr22:28,800,683–29,061,844, 6 genes (within-gene range 0–1): Z93930.2, Z93930.1, ZNRF3, ZNRF3-IT1, ZNRF3-AS1, C22orf31.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 25,124. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
